Gene-level copy-number profile of tumor specimen TCGA-A2-A1FW-01A from TCGA case TCGA-A2-A1FW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.4 years (22,779 days).
Specimen TCGA-A2-A1FW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b8ee56ee-5cac-45d1-af7d-d89eb8fa3360.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A1FW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b521a140-ba9b-4133-9d22-180778ada94e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 850; copy number 2: 3,253; copy number 3: 25,122; copy number 4: 19,304; copy number 5: 4,710; copy number 6: 2,009; copy number 7: 1,571; copy number 8: 556; copy number 9: 1,173; copy number 10: 133; copy number 11: 210; copy number 12: 190; copy number 13: 185; copy number 14: 217; copy number 15: 91; copy number 16: 55; copy number 17: 1; copy number 19: 58; copy number 21: 49; copy number 25: 82.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A1FW-01A-11D-A13J-01): tumor purity 0.85, ploidy 3.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,571 genes in 61 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,048,576–151,538,692, 121 genes, copy number 9–12 (broad region; genes not listed).
- chr1:154,469,772–155,331,114, 55 genes, copy number 8–14: SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1, AL592078.2, CHRNB2, AL592078.1, ADAR, AL606500.1, KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1.
- chr1:167,052,836–167,427,345, 7 genes, copy number 7 (within-gene range 2–7): GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2, POU2F1, AL136984.1.
- chr1:173,417,793–175,335,459, 44 genes, copy number 7–11: PRDX6-AS1, PRDX6, SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1.
- chr1:182,096,338–182,830,384, 20 genes, copy number 7 (within-gene range 5–7): LINC01344, AL390856.1, YPEL5P1, RNU6-152P, AL513480.1, EIF1P3, GLUL, TEDDM1, LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL.
- chr1:188,508,538–189,133,292, 8 genes, copy number 12: AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75.
- chr1:189,989,570–190,494,297, 5 genes, copy number 10: AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1.
- chr1:199,006,040–199,393,307, 6 genes, copy number 13: LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1.
- chr1:200,147,531–204,213,988, 135 genes, copy number 8–19 (within-gene range 5–19) (broad region; genes not listed).
- chr1:208,972,454–209,734,949, 19 genes, copy number 12 (within-gene range 2–12): LINC01774, AC104465.1, AC092810.3, AC092810.2, AC092810.1, TFDP1P1, ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2, CAMK1G, LAMB3, MIR4260, HSD11B1-AS1, G0S2, HSD11B1.
- chr1:218,983,023–220,148,041, 18 genes, copy number 12 (within-gene range 2–12): LYPLAL1-DT, LYPLAL1, RIMKLBP2, AL360093.1, AC096642.1, AC096642.2, LYPLAL1-AS1, AL356364.1, ZC3H11B, SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12.
- chr4:38,366,914–45,480,136, 129 genes, copy number 8–11 (broad region; genes not listed).
- chr5:42,423,439–45,895,970, 61 genes, copy number 7 (broad region; genes not listed).
- chr5:65,020,038–66,572,546, 29 genes, copy number 14: AC092354.2, AC092354.1, Y_RNA, ADAMTS6, AC008868.1, RPEP1, AC025186.1, AC025176.1, CENPK, PPWD1, TRIM23, RNU6-540P, TRAPPC13, SHLD3, SGTB, NLN, AC008958.1, AC010359.2, ERBIN, AC010359.1, AC010359.3, AC025442.2, SREK1, AC025442.1, LINC02065, AC092353.1, AC092353.2, LINC02229, PPIAP78.
- chr6:85,650,491–85,777,755, 7 genes, copy number 11: SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1, RNU4-72P, Y_RNA.
- chr6:86,170,447–86,768,932, 6 genes, copy number 11: RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P, AL353133.1, AL353133.2.
- chr7:130,070,534–130,687,432, 26 genes, copy number 9: KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2.
- chr7:139,777,051–140,479,536, 15 genes, copy number 8 (within-gene range 2–8): TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1.
- chr7:140,690,777–141,655,244, 17 genes, copy number 9 (within-gene range 2–9): NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1, CCT4P1, MRPS33, RNU4-74P, TMEM178B, AC006362.1, NDUFB10P2, AC005692.3, AC005692.1, AC005692.2, AC073878.1, AC073878.2, AGK.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7–9 (broad region; genes not listed).
- chr10:49,734,641–50,625,163, 21 genes, copy number 8 (within-gene range 3–8): OGDHL, MAPK6P6, RPL21P89, PARG, RPL35AP24, TIMM23B, TIMM23B-AGAP6, SNORA74C-2, RNA5SP317, AL442003.1, AGAP6, FAM21EP, SLC9A3P3, WASHC2A, SLC9A3P1, ASAH2, DYNC1I2P1, SGMS1, AC069547.2, AC069547.1, AL117341.1.
- chr10:73,007,217–75,431,588, 94 genes, copy number 11 (within-gene range 5–11) (broad region; genes not listed).
- chr10:75,450,081–75,743,755, 5 genes, copy number 11: AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr10:83,067,962–85,607,213, 33 genes, copy number 11: RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5, AL358787.2, LINC01519, AL358787.1, LINC02647, AC025428.1, LINC01520, AL731532.1, RNU6-325P, AL731532.2, GRID1-AS1.
- chr10:89,786,610–90,225,443, 7 genes, copy number 10 (within-gene range 3–10): MTND5P42, LINC00865, MARK2P16, LINC01374, LINC01375, SNRPD2P1, AL139340.1.
- chr10:102,918,294–104,624,795, 47 genes, copy number 8 (within-gene range 2–8): CNNM2, AL356608.2, NT5C2, RPS15AP29, MARCKSL1P1, ST13P13, RPEL1, INA, PCGF6, RNU11-3P, TAF5, ATP5MD, MIR1307, PDCD11, CALHM2, AL139339.2, AL139339.1, CALHM1, CALHM3, NEURL1-AS1, NEURL1, AL121929.1, AL121929.3, SH3PXD2A, AL121929.2, Y_RNA, SH3PXD2A-AS1, AL133355.1, STN1, SLK, RN7SL524P, COL17A1, MIR936, SFR1, CFAP43, MIR609, GSTO1, MIR4482, GSTO2, ITPRIP, AL162742.1, AL162742.2, ITPRIP-AS1, CFAP58-DT, CFAP58, LINC02620, AL161646.1.
- chr10:106,550,106–110,511,533, 30 genes, copy number 10: RPL23AP59, SORCS1, AL133395.1, RNA5SP325, RNA5SP326, LINC01435, PTGES3P5, AL353740.1, LINC02661, MAPKAPK5P1, RN7SKP278, RNU5B-6P, RNU6-839P, PHB2P1, BTF3P15, AL390123.1, XIAPP1, RPL21P91, XPNPEP1, RNU4-5P, ADD3-AS1, ADD3, SNRPGP12, MXI1, AL360182.2, AL360182.1, SMNDC1, AL355512.1, HMGB3P5, DUSP5.
- chr10:110,642,678–115,948,999, 79 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr11:63,759,892–69,675,416, 335 genes, copy number 7 (broad region; genes not listed).
- chr13:23,979,700–26,025,851, 48 genes, copy number 8 (within-gene range 5–8): AL359736.1, SPATA13, AL445985.1, IPO7P2, MIR2276, SPATA13-AS1, C1QTNF9, C1QTNF9-AS1, AL359736.2, NUS1P3, LINC00566, CYCSP33, TPTE2P6, PARP4, AL359538.4, AL359538.3, PSPC1P2, AL359538.1, AL359538.2, ATP12A, RNY1P7, RPL26P34, AL391560.1, IRX1P1, AL391560.2, ANKRD20A10P, RNF17, CENPJ, TPTE2P1, AL354798.1, SLC25A15P3, RPL34P27, LSP1P1, AL590099.1, PABPC3, AL359757.2, AMER2, LINC01053, LINC00463, AL359757.1, LINC01076, RPL23AP69, MTMR6, AL590787.1, NUP58, ELOBP1, ATP8A2, RNU6-78P.
- chr13:32,303,699–32,428,311, 5 genes, copy number 8 (within-gene range 3–8): ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1.
- chr17:28,219,285–30,360,566, 141 genes, copy number 13 (broad region; genes not listed).
- chr17:33,013,087–37,056,871, 158 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr17:48,037,161–55,561,577, 209 genes, copy number 7–19 (broad region; genes not listed).
- chr17:55,882,301–68,551,319, 387 genes, copy number 7–25 (within-gene range 2–25) (broad region; genes not listed).
- chr17:69,577,251–70,368,916, 11 genes, copy number 9–17 (within-gene range 6–17): LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1.
- chr20:157,454–5,197,887, 161 genes, copy number 7–16 (broad region; genes not listed).
- chr20:7,347,451–8,043,512, 8 genes, copy number 9–12: LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1.
- chr20:33,316,869–40,854,229, 209 genes, copy number 7 (broad region; genes not listed).
- chr20:53,196,229–64,313,132, 286 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 850. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
